FM case AD6918 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/aade9e30-983f-4491-a176-c37f17ac0520

Female, 56.0 years: Melanoma, NOS (ICD-O-3 8720/3) of the eye; primary biopsied or resected from the eye. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
